Surgical pathology report (de-identified scan), TCGA case TCGA-N7-A59B, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Washington University, specimen TCGA-N7-A59B-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

UTERUS WITH CERVIX, BILATERAL TUBES AND OVARIES, AND UPPER VAGINECTOMY; TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY

- CARCINOSARCOMA (MALIGNANT MIXED MULLERIAN TUMOR), CONFINED TO ENDOMETRIAL POLYP WITH PREDOMINANTLY CARCINOMATOUS AREAS
- UTERINE INTRAEPITHELIAL SEROUS CARCINOMA, FOCAL
- CERVIX WITH PATCHY ATROPHY AND CHRONIC INFLAMMATION
- BILATERAL OVARIES WITH EPITHELIAL INCLUSION CYSTS
- HYDROSALPINX, RIGHT
- LEFT FALLOPIAN TUBE WITH NO HISTOPATHOLOGIC ABNORMALITY
- SEE SYNOPSIS AND COMMENT

LYMPH NODE, SMALL BOWEL MESENTERY, EXCISION (INCLUDING FS1)
- ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1)

SOFT TISSUE, RECTOVAGINAL SEPTUM, "NODULE", EXCISION (INCLUDING FS2)
- BENIGN FIBROCONNECTIVE TISSUE WITH ENDOSALPINGIOSIS
- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION
- FIVE LYMPH NODES NEGATIVE FOR MALIGNANCY (0/5)

LYMPH NODES, RIGHT OBTURATOR, EXCISION
- THREE LYMPH NODES NEGATIVE FOR MALIGNANCY (0/3)

LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION
- ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1)

LYMPH NODE, LEFT OBTURATOR, EXCISION
- ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1)

LYMPH NODE, LEFT PARAAORTIC, EXCISION
- ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1)

LYMPH NODES, RIGHT PARAAORTIC, EXCISION
- FOUR LYMPH NODES NEGATIVE FOR MALIGNANCY (0/4)

OMENTUM, PARTIAL OMENECTOMY

ICD-6-3
Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8954/3
Site: Cervix Uteri, Endometrium
0541

Disc Is (Circle):		

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

- BENIGN ADIPOSE TISSUE WITH NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

Three intraoperative consultations were obtained and interpreted as:

#1 "Called to pick up 'uterus, cervix, BSO, upper vagina' is a 103 gram specimen consisting of a uterus measuring 9 cm x 7 cm x 4 cm, bilateral fallopian tubes and ovaries. The specimen is opened to show a 3.0 x 1.0 cm polypoid mass that appears superficial. There is no definitive invasion identified. The specimen is shown to the surgeon and small pieces of tumor and normal tissue are taken for study. Remainder for permanents," by

#2 "FS1": Small bowel mesentery node
- No evidence of malignancy, by

#3: "FS2B (1.2 x 1.0 x 0.1 cm) is inked and serially sectioned. The specimen is submitted for frozen section,"

FS2 (A-B): Pelvic node/rectovaginal septum
- A - Benign cyst with calcifications,
- B - Fibrosis, no evidence of malignancy,

Microscopic Description and Comment:

Sections from the polypoid mass show involvement by a malignant tumor with predominantly epithelial areas that are composed of high grade carcinoma including papillary serous foci. In addition a few solid areas are present; these areas are quite undifferentiated and could represent either poorly differentiated carcinomatous or sarcomatous (epithelioid) areas. Nonetheless, presence of a rare focus of malignant spindled cells argues for a diagnosis of carcinosarcoma. No heterologous elements are identified in the material examined. This case is also shown to who concurs with the stated diagnosis.

Background endometrium shows, focal, presence of intraepithelial serous carcinoma.

History:

The patient is a year old woman with a diagnosis of high-grade adenocarcinoma, mixed type with endometrioid and serous papillary features. This was diagnosed at an outside facility but reviewed here. The comment on the specimen was suspicious for carcinosarcoma. Preoperative imaging was not suggestive of any distant metastases. Operative procedure: Total abdominal hysterectomy with bilateral salpingo-oophorectomy and staging.

Specimen(s) Received:

- A: SMALL BOWEL MESENTARY NODE
- B: PELVIC NODULE/ RECTO VAGINAL SEPTUM
- C: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, UPPER VAGINA
- D: LYMPH NODE, RIGHT EXTERNAL ILIAC
- E: LYMPH NODE, RIGHT OBTURATOR
- F: LYMPH NODE, LEFT EXTERNAL ILIAC
- G: LYMPH NODE, LEFT OBTURATOR

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

H: LYMPH NODE, LEFT PARA AORTIC
I: LYMPH NODE, RIGHT PARA AORTIC
J: OMENTUM

Gross Description:

The specimens are received in ten separate formalin-filled containers, each labeled *

The first container is labeled "small bowel mesentery node." It holds a green cassette marked "FS1." The green cassette holds a 1.5 x 1.2 x 0.3 cm lymph node and surrounding adipose tissue. Entirely submitted. Labeled A1. Jar 0.

The second container is labeled "pelvis nodule, rectovaginal septum." It holds two green cassettes. One is marked "FS2A" and the other is "FS2B." The "FS2A" cassette holds two irregular fragments of fibroadipose tissue, 1.0 x 0.6 x 0.3 cm and 1.3 x 0.5 x 0.3 cm. Entirely submitted as B1. The "FS2B" cassette holds four irregular fragments of tissue, 1.2 x 0.4 x 0.2 cm to 1.3 x 0.3 x 0.2 cm. Entirely submitted as B2. Jar 0.

The third container is labeled "uterus, cervix, BSO, upper vagina." It contains a uterus with attached adnexa as described above. The serosal surface of the uterus is tan and smooth and glistening without adhesions or other abnormalities. The 2.5 x 2.5 cm tan ectocervix has multiple pinpoint areas of dark-red congestion. The 3.3 cm long endocervical canal is lined by tan pink mucosa. The 4.0 x 3.3 cm endometrial cavity contains a 3.5 x 1.4 cm tan polypoid mass in the posterior wall near the lower uterine segment junction. It appears to be confined to the endometrial surface and is attached to the endometrium by a narrow stalk. The myometrium measures 2.4 cm in greatest thickness. The 1.4 x 0.7 x 0.7 cm right ovary is normal in appearance. The 3.8 x 0.7 cm right fallopian tube is also normal in appearance. The left ovary is 2.5 x 1.2 x 0.7 cm and has a 0.2 cm clear cyst on its surface. The left tube is 3.7 x 0.8 cm and appears normal. Representative sections are submitted. Labeled C1 - anterior ectocervix; C2 - anterior lower uterine segment; C3 - anterior fundus (full-thickness); C4 - posterior cervix; C5 - lower uterine segment; C6 - posterior fundus with polypoid mass; C7 and C9 - additional sections of polypoid mass of the posterior fundus; C10 - right ovary and tube; C11 - left ovary; C12 - left tube. C13 - polypoid mass from endometrial cavity. Jar 3.

The fourth container is labeled "right external iliac lymph nodes." It holds a 9.5 x 3.2 x 0.7 cm irregular fragment of fibroadipose tissue. Three lymph nodes are dissected out, 1.3 x 0.6 x 0.4 cm, 1.7 x 0.7 x 0.3 cm, and 3.5 x 2.2 x 0.6 cm. The lymph nodes are entirely submitted. Labeled D1 to D3 - largest lymph serially sectioned x 7; D4 - second largest node bisected; D5 - smallest node bisected; D6 - two possible lymph nodes. Jar 1.

The fifth container is labeled "right obturator lymph node." It holds a 7.0 x 3.2 x 1.0 cm irregular fragment of fibroadipose tissue. Three lymph nodes are dissected out, 0.7 x 0.6 x 0.3 cm, 1.3 x 0.8 x 0.8 cm, and 4.4 x 2.0 x 0.6 cm. The lymph nodes are entirely submitted. Labeled E1 to E4 - largest lymph node serially sectioned x 9; E5 - second largest lymph node bisected; E6 - smallest lymph node bisected. Jar 1.

The sixth container is labeled "left external iliac lymph node." It holds two irregular fragments of fibroadipose tissue, 5.5 x 3.5 x 0.4 cm and 4.9 x 3.6 x 0.7 cm. One lymph node is dissected out, 3.5 x 2.2 x 0.6 cm. The specimen is serially sectioned x 7, and entirely submitted in cassettes labeled F1 to F3. Jar 1.

The seventh container is labeled "left obturator." It holds two irregular fragments of fibroadipose tissue, 2.7 x 2.0 x 1.4 cm and 5.2 x 2.2 x 1.2 cm. One lymph node is dissected out, 3.4 x 1.2 x 0.7 cm. The lymph node is serially sectioned and entirely submitted in cassettes labeled G1 and G2. Jar 1.

The eighth container is labeled "left paraaortic lymph node." It holds a 4.5 x 2.0 x 0.9 cm irregular fragment of fibroadipose tissue. A 2.2 x 1.7 x 0.4 cm lymph node is dissected out. The lymph node is bisected and entirely submitted in H1 and H2. Jar 1.

The ninth container is labeled "right paraaortic lymph node." It holds three fragments of tissue, 1.0 x 0.6 x 0.3 cm, 1.4 x 0.9 x 0.5 cm, 3.5 x 2.0 x 0.6 cm. Four possible lymph nodes are dissected out, 1.0 x 0.5 x 0.5 cm to 1.9 x 1.0 x 0.4 cm. The lymph nodes are entirely submitted. Labeled I1 - smallest lymph node bisected; I2 - one lymph node bisected; I3 - one lymph node bisected; I4 - one lymph node bisected. Jar 1.

The tenth container is labeled "omental biopsy." It holds a 7.5 x 5.0 x 0.6 cm fragment of fibroadipose tissue. There are no visible or palpable masses or lesions associated with the surface or on cut section. Representative sections are submitted. Labeled J1 to J4 - random sections of omental biopsy. Jar 3.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS

Uterus, Cervix, Bilateral Tubes and Ovaries, Upper Vagina

HISTOPATHOLOGIC TYPE

The histologic diagnosis is malignant mixed mullerian tumor, not otherwise specified

TUMOR INVASION

Invasive tumor is absent (intraendometrial tumor only)

LOWER UTERINE SEGMENT INVOLVEMENT

(does not change the stage)

The lower uterine segment is not involved by tumor

ENDOCERVICAL INVOLVEMENT

The endocervix is not involved by tumor

LYMPHVASCULAR SPACE INVASION

Lymphovascular space invasion by tumor is absent

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

The regional lymph nodes are free of tumor in 16 nodes

The regional lymph nodes are involved by tumor in 0 nodes

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

PRIMARY TUMOR (TNM Category/FIGO Stage)

Tumor limited to the endometrium or invades less than one-half of the myometrium (T1a/IA)

STAGE GROUPING

T1aN0Mx

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 51966b83-f4f9-4f46-bbcf-ab003f691a99 (TCGA-N7-A59B.3B9F80E7-26D2-4F99-B070-37715ECAC9AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).